Gene-level copy-number profile of tumor specimen TCGA-99-8033-01A from TCGA case TCGA-99-8033, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.9 years (27,342 days).
Specimen TCGA-99-8033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2557e6de-4f50-4b1f-a1f3-9fae683d41e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-99-8033-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ce5208b-4887-4b6c-971c-ca9e4a6748ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,902; copy number 2: 19,931; copy number 3: 12,616; copy number 4: 19,234; copy number 5: 2,721; copy number 6: 380; copy number 7: 1,966; copy number 9: 39; copy number 21: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-99-8033-01A-11D-2237-01): tumor purity 0.29, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,132 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–7 (broad region; genes not listed).
- chr2:139,668,547–222,946,388, 1,263 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–41,071,342, 636 genes, copy number 5–7 (broad region; genes not listed).
- chr11:101,451,564–104,609,498, 59 genes, copy number 5: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552.
- chr15:19,878,555–26,949,208, 304 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:33,578,219–49,470,223, 190 genes, copy number 7–21 (within-gene range 3–21) (broad region; genes not listed).
- chr19:21,634,833–23,147,221, 76 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 481. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
